Gene-level copy-number profile of tumor specimen TCGA-FD-A6TD-01A from TCGA case TCGA-FD-A6TD, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Anterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 77.6 years (28,328 days).
Specimen TCGA-FD-A6TD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.a498d3fe-72fa-4c94-b12e-0144202e5a94.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FD-A6TD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b28ec79a-0279-4380-bdfe-f3f2f314ab9b

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 17,141; copy number 3: 21,483; copy number 4: 15,299; copy number 5: 5,379; copy number 6: 51; copy number 7: 188; copy number 8: 39; copy number 9: 135; copy number 11: 64; copy number 12: 14; copy number 13: 18; copy number 19: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FD-A6TD-01A-51D-A338-01): tumor purity 0.37, ploidy 3.01, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 461 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:35,429,064–36,588,661, 22 genes, copy number 7: U3, SPEF2, RNU7-130P, AC137810.1, IL7R, AC112204.3, AC112204.1, CAPSL, AC112204.2, UGT3A1, UGT3A2, AC016612.1, LMBRD2, MIR580, SKP2, RNU6-1305P, NADK2, NADK2-AS1, RANBP3L, AC114277.1, RNA5SP181, AC010631.1.
- chr5:37,953,402–41,071,342, 49 genes, copy number 7–12: AC034226.1, LINC02119, AC010338.1, EGFLAM, EGFLAM-AS4, EGFLAM-AS3, EGFLAM-AS2, EGFLAM-AS1, AC091839.1, AC010457.1, LIFR, LIFR-AS1, MIR3650, AC010425.1, OSMR-AS1, AC091435.1, AC091435.2, OSMR, RICTOR, AIG1P1, AC008964.1, FYB1, GOLGA5P1, C9, DAB2, LINC02104, CCDC11P1, INTS6P1, GCSHP1, LINC00603, KRT18P56, LINC00604, RNU1-150P, AC108105.1, AC093277.1, AC114977.1, AC114977.2, TTC33, SNORA63, PTGER4, PRKAA1, AC008810.1, RPL37, SNORD72, CARD6, C7, RNU7-161P, AC114967.1, MROH2B.
- chr5:50,396,192–60,522,120, 155 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr8:34,174,886–38,409,527, 75 genes, copy number 9–19 (within-gene range 5–19) (broad region; genes not listed).
- chr16:8,508,069–10,943,021, 63 genes, copy number 8–13 (within-gene range 6–13) (broad region; genes not listed).
- chr16:12,545,482–14,266,773, 26 genes, copy number 8 (within-gene range 2–8): AC131391.1, AC010333.1, AC010333.2, AC010333.3, CPPED1, MIR4718, AC109597.1, AC109597.2, AC092324.1, RPL35AP34, SHISA9, AC009134.1, U91319.1, AC003009.1, TMF1P1, U95743.1, ERCC4, RPS26P52, AC010401.1, AC010401.2, LINC02185, LINC02186, MRTFB, AC130650.2, AC130650.1, TVP23CP2.
- chr16:14,435,700–15,888,625, 58 genes, copy number 9 (within-gene range 2–9): PARN, RN7SL274P, BFAR, RNU7-125P, PLA2G10, AC009167.1, NPIPA3, AC136443.1, AC136443.4, NPIPA2, AC136443.2, ABCC6P2, NOMO1, AC136443.5, AC136443.3, MIR3179-1, MIR3670-1, AC138932.1, MIR3180-1, PKD1P3, Y_RNA, NPIPA1, MIR6511A1, MIR6770-1, AC138932.3, PDXDC1, AC138932.2, MIR1972-1, AC138932.4, NTAN1, RRN3, AC139256.1, NPIPP1, PKD1P6-NPIPP1, PKD1P6, MIR6511B2, Y_RNA, MIR3180-4, AC126763.1, AC137803.1, NPIPA5, MPV17L, AC140504.1, BMERB1, MARF1, AC026401.1, MIR6506, NDE1, MIR484, AC026401.2, AC026401.3, MYH11, AF001548.2, AF001548.1, AF001548.3, CEP20, RNU6-213P, AC130651.1.
- chr16:17,094,351–17,470,960, 7 genes, copy number 7 (within-gene range 2–7): TCERG1P2, AC109446.1, XYLT1, AC109446.2, AC099494.1, AC099494.2, AC099494.3.
- chr16:22,545,698–23,026,285, 6 genes, copy number 8 (within-gene range 2–8): OTOAP1, AC009021.2, AC009021.1, AC130466.1, HS3ST2, AC127459.2.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
